Surgical pathology report (de-identified scan), TCGA case TCGA-WC-AA9E, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-AA9E-01A (Primary Tumor).

Accession:

Specimen Date/Time:

ICD O-3

Melanoma, spindle cell, type B 8774/3

Site: (L) Choroid C69.3

6/13/14

DIAGNOSIS

(A) TISSUE FROM LEFT ORBIT:

CONSISTENT WITH RECURRENT MELANOMA, SPINDLED B MORPHOLOGY, See comment.

COMMENT

The tumor is viable with minimal necrosis < 5%. Focal background fibrous tissue is present invaded by tumor, the remainder of the sample is tumor. The morphology is consistent with the prior history of uveal melanoma.

PATHOLOGIC STAGE BASED ON PATHOLOGY MATERIAL REVIEWED IN THIS ACCESSION

NA- recurrence

GROSS DESCRIPTION

(A) TISSUE FROM LEFT ORBIT – Multiple black, red, soft tissue fragments without discernible normal tissue (3 x 2 x 0.3 cm in aggregate). Portion of tissue submitted per protocol. Remainder of tissue submitted in A1-A4.

BIOMARKER TESTING

Recurrence - local Tumor Block: A4

CLINICAL HISTORY

History of uveal melanoma of the left eye

SNOMED CODES

T-D1480, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

This case allowable, per NCI Program Office.

Source: NCI Genomic Data Commons file e8040688-e44e-4ec9-9359-35dcd8082d5e (TCGA-WC-AA9E.28ADDF38-07FD-4354-8F17-C0E4310514C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).